Somatic mutation profile of tumor specimen TCGA-IG-A3YC-01A (aliquot TCGA-IG-A3YC-01A-11D-A247-09) from TCGA case TCGA-IG-A3YC, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 62.4 years (22,774 days).
Specimen TCGA-IG-A3YC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b7e76a6-ad7c-4cbd-b1e0-e83e1cf83e37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A3YC-10A (Blood Derived Normal), aliquot TCGA-IG-A3YC-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2363611-026e-43b4-a2b6-d04872f596cf

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 33, Silent 11, Frame Shift Ins 2, Nonsense Mutation 2, Translation Start Site 1, In Frame Del 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.437G>A p.W146* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | hotspot (GDC flag); catalogued as rs1206165503, CM107391, COSV52661900, COSV52703354, COSV52753201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDH2 | c.1521+2_1521+3del p.X507_splice | Splice Site (DEL) | VAF 10/52 reads (19%) | catalogued as rs1314909985; called by pindel, varscan2
- AP3B1 | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99670803; called by muse, mutect2, varscan2
- ARMC3 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs148669748; called by mutect2, varscan2
- B4GALT6 | c.720C>A p.Y240* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV52704231, COSV52704340; called by muse, mutect2, varscan2
- FAM83E | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748353296; called by muse, mutect2, varscan2
- FMN1 | c.4228C>T p.R1410C (on ENST00000616417 / NM_001277313.2; = p.R1187C on NM_001103184.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs866300506, COSV57929513; called by muse, mutect2, varscan2
- GUCY2D | c.3166C>A p.L1056I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM155803; called by muse, mutect2, varscan2
- HSPB7 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757356294; called by muse, mutect2, varscan2
- LRRC56 | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54247035; called by muse, mutect2, varscan2
- MPP5 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as rs774877439, COSV55528297, COSV55528976; called by mutect2, varscan2
- OR2M2 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs758856171, COSV62897962; called by muse, mutect2, varscan2
- OSBPL6 | c.1541A>T p.D514V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51930779; called by muse, mutect2, varscan2
- SLC6A3 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs533057143; called by muse, mutect2, varscan2
- THSD4 | c.2401del p.E801Sfs*22 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as COSV99029320; called by mutect2, pindel, varscan2
- ZNF488 | c.437A>G p.K146R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs140082282; called by muse, mutect2, varscan2
- ACACB | c.7008G>C p.E2336D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- C6orf118 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DEPDC1B | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ERV3-1 | c.929A>T p.E310V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- EYS | c.767T>A p.I256K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- GRAMD1B | c.1262A>T p.N421I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HEATR5A | c.5229C>G p.C1743W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL7R | c.1365C>G p.F455L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MED12L | c.1360G>C p.V454L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.329); called by muse, mutect2
- MGST3 | c.146A>T p.E49V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- NOL9 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- NRCAM | c.394G>T p.A132S (on ENST00000379028 / NM_001371124.1; = p.A126S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR8G5 | c.278_280del p.S93del | In Frame Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- PGAP3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2
- PRAMEF19 | c.497T>A p.F166Y | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGER4 | c.849C>G p.I283M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by mutect2, varscan2
- PTPN14 | c.2067_2068insT p.P690Sfs*11 | Frame Shift Ins (INS) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- SAMD9L | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SEL1L2 | c.1114dup p.I372Nfs*25 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by pindel, varscan2
- SOX5 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SREBF1 | c.2621A>T p.K874M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TFPI2 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM27 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZFPM2 | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.083); called by muse, varscan2
- ZNF671 | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CACNA2D1 | c.276C>T p.N92= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- CEP170 | c.360G>A p.Q120= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- CHRM3 | c.1653C>T p.F551= | Silent (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- COL5A3 | c.3753G>A p.E1251= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs758613882; called by muse, mutect2, varscan2
- DYRK1B | c.624C>T p.G208= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs746346346, COSV59912940; called by muse, mutect2
- GDF3 | c.924C>T p.S308= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- KRTAP4-3 | c.27C>T p.V9= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs369294684; called by muse, mutect2
- NAP1L3 | c.1105A>C p.R369= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- NKD2 | c.507C>T p.L169= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- PCBP2 | c.36C>A p.V12= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV63727975; called by muse, varscan2
- RPUSD1 | c.774C>T p.P258= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs144842334; called by muse, mutect2, varscan2
